Gene-level copy-number profile of tumor specimen ALCH-B27D-TTP1-A from ALCHEMIST case ALCH-B27D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.8 years (25,842 days).
Specimen ALCH-B27D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebcb98ce-742a-4a9d-879f-a55c75a2941d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/e1f55f8d-1deb-4d59-ba32-8d7e05c921f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 2,034; copy number 2: 55,355; copy number 3: 939; copy number 4: 7; copy number 5: 5; copy number 6: 2; copy number 7: 1; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:31,234,152–31,269,451, 1 gene: EHD3.
- chr2:241,849,884–241,858,894, 1 gene: PDCD1.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr6:170,282,206–170,306,565, 1 gene (within-gene range 0–2): DLL1.
- chr6:170,297,876–170,298,375, 1 gene (within-gene range 0–2): AL078605.1.
- chr7:100,821,027–100,821,264, 1 gene (within-gene range 0–1): RN7SL750P.
- chr8:7,768,977–7,829,053, 6 genes: FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A.
- chr8:43,542,076–43,544,057, 1 gene: AC134698.2.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr9:124,257,606–124,353,307, 3 genes: NEK6, AL162724.2, AL162724.1.
- chr11:57,450,183–57,477,534, 4 genes: RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr13:45,341,345–45,417,975, 3 genes (within-gene range 0–2): TPT1-AS1, AL138963.1, RCN1P2.
- chr13:113,667,219–113,737,736, 1 gene: GRK1.
- chr16:66,408,524–66,412,135, 1 gene: LINC00920.
- chr17:2,689,386–2,749,504, 7 genes (within-gene range 0–2): CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:16,415,571–16,437,003, 2 genes (within-gene range 0–2): TRPV2, AC093484.1.
- chr17:16,439,505–16,441,298, 4 genes (within-gene range 0–2): SNORD49B, SNORD49A, AC093484.4, SNORD65.
- chr17:61,393,456–61,413,280, 3 genes (within-gene range 0–2): TBX2-AS1, TBX2, LINC02875.
- chr18:59,267,035–59,274,086, 1 gene: RAX.
- chr19:4,639,516–4,670,362, 3 genes: TNFAIP8L1, MYDGF, AC005339.1.
- chr20:21,511,017–21,514,064, 2 genes: NKX2-2, NKX2-2-AS1.
- chr20:62,804,835–62,814,000, 1 gene (within-gene range 0–2): OGFR.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,107,808–136,124,363, 3 genes, copy number 5: LINC02846, TMEM250, AL138781.1.
- chr12:132,277,349–132,280,900, 2 genes, copy number 5 (within-gene range 2–5): AC148477.2, AC148477.5.
- chr17:78,870,910–78,903,217, 2 genes, copy number 6 (within-gene range 2–6): CEP295NL, AC100788.2.
- chr21:43,053,191–43,107,570, 2 genes, copy number 7–30: CBS, U2AF1.

Autosomal genes at a single copy (total copy number 1): 1,402. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
